Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5694, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5694-01A (Primary Tumor).

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Left renal lesion.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Laparoscopic assisted left nephrectomy.

FINAL DIAGNOSIS:**KIDNEY, LEFT, NEPHRECTOMY -**

- A. RENAL CELL CARCINOMA, CLEAR CELL TYPE.
- B. FUHRMAN NUCLEAR GRADE IS 3 of 4.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 6.0 cm.
- D. THE NEOPLASM DOES NOT INVOLVE THE PERIRENAL OR PERIPELVIC FAT.
- E. THE NEOPLASM GROSSLY EXTENDS INTO THE RENAL VEIN AND BUT IS NOT PRESENT AT THE RENAL VEIN MARGIN.
- F. ALL SURGICAL MARGINS ARE FREE OF THE NEOPLASM.
- G. NON-NEOPLASTIC KIDNEY SHOWS CHRONIC INTERSTITIAL INFLAMMATION, GLOMERULOSCLEROSIS, AND THYROIDIZATION.
- H. TNM STAGE: pT3b NX MX.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY KIDNEY TUMORS**

SPECIMEN TYPE: Radical nephrectomy

LATERALITY: Left

TUMOR SITE: Lower pole

FOCALITY: Unifocal

TUMOR SIZE: Greatest dimension: 6.0 cm
Additional dimensions: 6.0 cm

MACROSCOPIC EXTENT OF TUMOR: Tumor extension into major veins

HISTOLOGIC TYPE: Clear cell (conventional) renal carcinoma

HISTOLOGIC GRADE (Fuhrman Nuclear Grade): G2

PATHOLOGIC STAGING (pTNM): pT3b

pNX

Number of regional lymph nodes examined: 0

pMX

MARGINS: Margins uninvolved by invasive carcinoma

ADRENAL GLAND: Not present

VENOUS (LARGE VESSEL) INVASION (V): Absent

LYMPHATIC (SMALL VESSEL) INVASION (L): Absent

ADDITIONAL PATHOLOGIC FINDINGS: Glomerular disease (type): GLOMERULOSCLEROSIS

Interstitial disease (type): CHRONIC INFLAMMATION

Other: THYROIDIZATION

Source: NCI Genomic Data Commons file 39a45891-c744-4297-af34-a6345367fe4d (TCGA-B0-5694.C28C9873-1DA9-4647-854F-A71E0D5CBD89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).